Gene-level copy-number profile of tumor specimen TCGA-24-1418-01A from TCGA case TCGA-24-1418, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.0 years (24,842 days).
Specimen TCGA-24-1418-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d6aa4ef8-9bba-4e65-b546-b7a468bffe34.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1418-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f6d102ab-adf1-4712-a837-6d5725062c93

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 4,150; copy number 2: 16,828; copy number 3: 21,927; copy number 4: 13,242; copy number 5: 2,800; copy number 6: 365; copy number 7: 84; copy number 8: 263; copy number 9: 151.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1418-01A-01D-0472-01): tumor purity 0.77, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,981,722–79,264,573, 10 genes: AC027279.3, AC027279.2, AC009145.4, AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3, AC092376.1, RNA5SP431.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 498 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,931,064–2,119,926, 1 gene, copy number 7 (within-gene range 6–7): AC124852.1.
- chr5:2,184,710–4,866,311, 22 genes, copy number 7 (within-gene range 6–7): Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1.
- chr5:133,574,829–133,575,298, 1 gene, copy number 9: AC010608.2.
- chr12:63,271,404–71,118,247, 176 genes, copy number 7–9 (broad region; genes not listed).
- chr12:115,810,359–124,725,934, 273 genes, copy number 7–8 (broad region; genes not listed).
- chr20:2,652,593–3,160,196, 25 genes, copy number 8 (within-gene range 5–8): NOP56, MIR1292, SNORD110, SNORA51, SNORD86, SNORD56, SNORD57, IDH3B, AL049712.1, EBF4, RPL19P1, CPXM1, AL035460.1, C20orf141, TMEM239, PCED1A, VPS16, PTPRA, GNRH2, MRPS26, OXT, AVP, RN7SL555P, UBOX5-AS1, UBOX5.

Autosomal genes at a single copy (total copy number 1): 1,729. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
